Surgical pathology report (de-identified scan), TCGA case TCGA-39-5024, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5024-01A (Primary Tumor).

[page 1 of 5]
TCGA-39-5024

with right mid lobe mass, bronchial _____
consistent with squamous cell CA.

Specimens Submitted:

- 1: SP: Level seven lymph node
- 2: SP: Level seven lymph node #2
- 3: SP: Right level 10 lymph node
- 4: SP: Right level 4 lymph node
- 5: SP: Level 7 lymph node
- 6: SP: Right level 10 lymph node
- 7: SP: Right lung

DIAGNOSIS:

- 1) LYMPH NODE, LEVEL VII; BIOPSY:
- METASTATIC NON-SMALL CELL CARCINOMA, SEEN IN FROZEN SECTION.
- 2) LYMPH NODE, LEVEL VII; BIOPSY:
- BENIGN LYMPH NODE.
- 3) LYMPH NODE, LEVEL X, RIGHT; BIOPSY:
- BENIGN LYMPH NODE.
- 4) LYMPH NODE, LEVEL IV, RIGHT; BIOPSY:
- FRAGMENTS OF BENIGN LYMPH NODES WITH FOCAL NECROSIS AND CALCIFICATIONS.
- NO MYCOBACTERIAL OR FUNGAL ORGANISMS ARE SEEN ON STAINS FOR AFB, FITE AND GMS.
- 5) LYMPH NODE, LEVEL VII; BIOPSY:
- BENIGN FRAGMENTED LYMPH NODES.
- 6) LYMPH NODES, LEVEL X, RIGHT; BIOPSY:
- BENIGN LYMPH NODE.
- 7) LUNG, RIGHT; PNEUMONECTOMY:
- SQUAMOUS CELL CARCINOMA OF THE RIGHT LUNG HILUM, MODERATELY DIFFERENTIATED.
- THE TUMOR'S GREATEST DIAMETER IS 3.8 x 3.5 x 2.8 CM.

** Continued on next page **

[page 2 of 5]
- EXTENSIVE VASCULAR INVASION IS PRESENT.
- NO PERINEURAL INVASION IS IDENTIFIED.
- THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.
- THE TUMOR INVADES THE BRONCHUS.
- THE PLEURA IS FREE OF TUMOR.
- RESPIRATORY BRONCHIOLITIS, FOCAL ORGANIZING PNEUMONIA.
- METASTATIC TUMOR IS PRESENT IN ONE OF EIGHT PERIBRONCHIAL LYMPH NODE

BY DIRECT EXTENSION
(1/8).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:
Result

Special Stain
APB
FITE
GMS

Comment

1). The specimen is received fresh for frozen section consultation, labeled "Level 7 lymph node" and consists of a single anthracotic soft tissue fragment measuring 0.6 x 0.5 x 0.3 cm. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

2). The specimen is received fresh for frozen section consultation, labeled "Level 7 lymph node number two" and consists of two pieces of lymphoid tissue measuring 0.7 x 0.5 x 0.2 cm in aggregate. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

** Continued on next page **

[page 3 of 5]
3). The specimen is received fresh for frozen section consultation, labeled "Right level 10 lymph node" and consists of a lymph node with attached fatty tissue measuring 1.6 x 1.5 cm. Entirely submitted for frozen section.

4). The specimen is received fresh for frozen section consultation, labeled "Right level 4 lymph nodes" and consists of multiple fragments of lymphoid appearing tissue ranging from 0.1 to .4 cm at greatest dimension, submitted for frozen section consultation in two cassettes. Separately received in container are two irregular shaped pieces of fatty gray-tan tissue totaling 3 x 2.5 x 0.3 cm, with focal possible lymphoid areas noted. The remaining tissue submitted separately.

Summary of sections:

FSCA -- frozen section control A

FSCB frozen section control B

RT remaining tissue

5). The specimen is received in formalin and is labeled "Level 7 lymph node" and consists of multiple lymph nodes measuring from 0.2 to 0.7 cm. Entirely submitted in two cassettes.

Summary of sections:

L. N-lymph nodes

6). The specimen is received in formalin and is labeled "Right level 10 lymph nodes" and consists of one lymph node measuring 0.8 cm in greatest diameter. The specimen is submitted entirely in one cassette.

Summary of sections:

LN-lymph nodes

7). The specimen is received fresh and is labeled "Right lung" and consists of a pneumonectomy specimen, measuring 22 x 18 x 3.5 cm. A staple line is present adjacent to the bronchus. The posterior surface of the lung shows a sutured line measuring 6 cm. A subpleural tumor is palpated within 0.5 cm off the sutured line. On cut section the tumor appears to be largely peribronchial in location at the hilum and measures 3.8 x 3.5 x 2.8 cm. The surface has a white tan appearance. The tumor has a firm and gritty consistency. Numerous peribronchial lymph nodes are embedded within and

** Continued on next page **

[page 4 of 5]
around the tumor. No other tumor is identified within either off the lobe's in the remainder of the specimen. The parenchyma off the peripheral lung is grossly unremarkable. Photograph taken. Tissue submitted for TPS. Representative sections off the stapled margin, the tumor, bronchus, vascular margin and normal lung are taken.

Summary of sections:

BM-bronchial margin

V.M-vascular margin

PBLN-few bronchial lymph nodes

T-tumor

ADD B-additional bronchial margins adjacent to the tumor

NL- normal lung

Summary of Sections:

Part 1: SP: Level seven lymph node [REDACTED]

Block	Sect.	Site	PCs
1		fsc	1

Part 2: SP: Level seven lymph node #2 ([REDACTED] [REDACTED])

Block	Sect.	Site	PCs
1		fsc	1

Part 3: SP: Right level 10 lymph node ([REDACTED] [REDACTED])

Block	Sect.	Site	PCs
1		fsc	1

Part 4: SP: Right level 4 lymph node [REDACTED] [REDACTED]

Block	Sect.	Site	PCs
1		fsc	1
1		fscb	1
1		rt	1

Part 5: SP: Level 7 lymph node [REDACTED]

Block	Sect.	Site	PCs
2		ln	2

Part 6: SP: Right level 10 lymph node [REDACTED]

Block	Sect.	Site	PCs
1		ln	1

Part 7: SP: Right lung ([REDACTED])

Block	Sect.	Site	PCs
-------	-------	------	-----

** Continued on next page **

[page 5 of 5]
6	addB	6
1	bm	1
10	nl	10
1	pbln	1
1	sm	1
6	t	6
1	vm	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: METASTATIC NON-SMALL CELL CARCINOMA.
(SQ) PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: BENIGN LYMPH NODES. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 3) FROZEN SECTION DIAGNOSIS: BENIGN LYMPH NODES. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 4) FROZEN SECTION DIAGNOSIS: LYMPH NODE, WITH FOCAL NECROSIS
AND CALCIFICATION. NO VIABLE TUMOR SEEN. [REDACTED]
PERMANENT DIAGNOSIS: SAME.

** End of Report **

Source: NCI Genomic Data Commons file a9fe4f79-2e4c-4b44-b8b5-a06c51057d94 (TCGA-39-5024.EC84ADE8-8988-4735-BE04-97A52B8B8033.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).